Gene-level copy-number profile of tumor specimen TARGET-10-PATMXN-09A from TARGET case TARGET-10-PATMXN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.9 years (5,450 days).
Specimen TARGET-10-PATMXN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.0161a290-9c04-59dc-a9c0-e027319d335d.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATMXN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate.
https://portal.gdc.cancer.gov/files/4fdaa1e6-73db-4775-ac5d-c78f2b11f0e4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 4,737; copy number 2: 54,170; copy number 3: 1,323.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:127,170,011–127,170,231, 1 gene: NIFKP9.
- chr5:96,741,079–96,742,698, 1 gene: AC020900.1.
- chr9:21,239,002–22,128,103, 37 genes: IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr11:55,635,113–55,652,854, 2 genes: OR4P4, OR4S2.
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,347. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
